Somatic mutation profile of tumor specimen TCGA-37-4132-01A (aliquot TCGA-37-4132-01A-01D-1352-08) from TCGA case TCGA-37-4132, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 61.7 years (22,520 days).
Specimen TCGA-37-4132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2214bba-3fcf-4394-b164-cf321d019020.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-4132-10A (Blood Derived Normal), aliquot TCGA-37-4132-10A-01D-1352-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78610f5e-d111-407e-ae3f-5bae774548a0

The open-access MAF lists 318 somatic variants for this specimen: 249 protein-altering or splice-affecting, 59 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 59, Nonsense Mutation 12, Splice Site 8, Frame Shift Del 7, Intron 4, RNA 4, 5'UTR 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1D1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs267606650, CM044568, COSV54338727; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 70/235 reads (30%) | catalogued as rs1304351755, CM143129, COSV55170206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 136/308 reads (44%) | hotspot (GDC flag); catalogued as rs137853293, CM900196, COSV57296164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 40/103 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2918A>T p.N973I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101201208; called by muse, mutect2, varscan2
- ACKR1 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 144/437 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63674012; called by muse, mutect2, varscan2
- ACP6 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100984236; called by muse, mutect2, varscan2
- ADAMTS16 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99942100; called by muse, mutect2, varscan2
- ADAMTS6 | c.3257T>C p.V1086A | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as COSV58682196; called by muse, mutect2
- ADGRL3 | c.2861T>C p.L954S (on ENST00000506720 / NM_001322402.2; = p.L886S on NM_015236.6) | Missense Mutation (SNP) | VAF 210/676 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.326); catalogued as COSV101547295; called by muse, mutect2, varscan2
- ADK | c.583T>A p.S195T (on ENST00000286621; = p.S178T on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV99692930; called by muse, mutect2, varscan2
- AHNAK | c.10578G>T p.L3526F | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99948563; called by muse, mutect2, varscan2
- ALDH18A1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100973248; called by muse, mutect2, varscan2
- ALG12 | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 51/122 reads (42%) | PolyPhen benign (0.003); catalogued as COSV100427167; called by muse, mutect2, varscan2
- ALPK2 | c.1025C>A p.A342E | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100864564; called by muse, mutect2, varscan2
- ANGPT1 | c.1330A>C p.T444P | Missense Mutation (SNP) | VAF 144/248 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99863572; called by muse, mutect2, varscan2
- ANK2 | c.10091T>C p.L3364P | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100002969; called by muse, mutect2, varscan2
- APBA2 | c.1800G>C p.M600I | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV101258190; called by muse, mutect2, varscan2
- APC | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as CM106354, COSV57350231; called by muse, mutect2, varscan2
- APLF | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100377035, COSV58143978; called by muse, mutect2, varscan2
- ARHGAP39 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1374879925, COSV52773739; called by muse, mutect2, varscan2
- ARHGEF12 | c.4343T>C p.V1448A | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100755071; called by muse, mutect2
- ASB2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100279450; called by muse, mutect2, varscan2
- ATIC | c.919A>G p.R307G | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV99378015; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100377096; called by muse, mutect2, varscan2
- BSX | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.242); catalogued as COSV100545281; called by muse, mutect2, varscan2
- BSX | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100545283; called by muse, mutect2, varscan2
- BTN1A1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs771415855, COSV99764482; called by muse, mutect2
- C2CD2L | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100371371; called by muse, mutect2, varscan2
- CABP2 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 126/254 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as COSV53710049, COSV99590886; called by muse, mutect2, varscan2
- CACNG7 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV55813485, COSV99712157; called by muse, mutect2, varscan2
- CARNMT1 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100961102; called by muse, mutect2, varscan2
- CCDC33 | c.908G>T p.W303L | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100351663; called by muse, mutect2, varscan2
- CCDC85A | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV101339501; called by muse, varscan2
- CCL1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.295); catalogued as COSV99861784; called by muse, varscan2
- CCN4 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV99137264; called by muse, mutect2, varscan2
- CDC6 | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 188/546 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1250836098, COSV99266636; called by muse, mutect2, varscan2
- CDH20 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.091); catalogued as rs1182434562, COSV99405996; called by muse, mutect2, varscan2
- CDH23 | c.4607G>C p.S1536T | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.82); catalogued as COSV99822520; called by muse, mutect2
- CEMIP2 | c.2513A>G p.Y838C | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.775); catalogued as COSV100987136; called by muse, mutect2, varscan2
- CENPP | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 120/406 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV99845747; called by muse, mutect2, varscan2
- CERKL | c.991G>T p.D331Y (on ENST00000339098 / NM_001030311.2; = p.D305Y on NM_201548.5) | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183937; called by muse, mutect2, varscan2
- CFAP44 | c.1594A>T p.I532F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV99870079; called by muse, mutect2, varscan2
- CLCNKB | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV65161369; called by muse, mutect2, varscan2
- CLPTM1 | c.1518G>T p.W506C | Missense Mutation (SNP) | VAF 128/498 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100493877; called by muse, mutect2, varscan2
- CPA3 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936288; called by muse, mutect2, varscan2
- CRB1 | c.3152G>T p.W1051L | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM130793, COSV100958001; called by muse, mutect2, varscan2
- CRB1 | c.3153G>T p.W1051C | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100958002; called by muse, mutect2, varscan2
- CREBBP | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99270980; called by muse, mutect2
- CRISP1 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV100237008; called by muse, mutect2
- CUZD1 | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100158912; called by muse, mutect2, varscan2
- DACH1 | c.1727-1G>C p.X576_splice (on ENST00000619232 / NM_001366712.1; = p.X322_splice on NM_004392.6) | Splice Site (SNP) | VAF 190/581 reads (33%) | catalogued as COSV100498837; called by muse, mutect2, varscan2
- DDX23 | c.1070G>T p.W357L | Missense Mutation (SNP) | VAF 151/491 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339919; called by muse, mutect2, varscan2
- DEF8 | c.280G>A p.E94K (on ENST00000268676 / NM_207514.3; = p.E33K on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99240645; called by muse, mutect2, varscan2
- DGKD | c.1744A>G p.S582G (on ENST00000264057 / NM_152879.3; = p.S538G on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/319 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs764791542, COSV99896969; called by muse, mutect2, varscan2
- DLD | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99227320, COSV99227338; called by muse, mutect2, varscan2
- DNAH17 | c.12494C>T p.T4165M | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543663107, COSV99428389; called by muse, mutect2, varscan2
- DNAH5 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99452005; called by muse, mutect2, varscan2
- DNAH7 | c.4069G>T p.G1357W | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416355; called by muse, mutect2, varscan2
- DNAH8 | c.5822C>T p.P1941L | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100546454; called by muse, mutect2, varscan2
- DNAJC13 | c.2219A>G p.Q740R | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99607701; called by muse, mutect2, varscan2
- DNAJC30 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV99736778; called by muse, mutect2, varscan2
- DOCK7 | c.1798C>G p.P600A | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99225272; called by muse, mutect2, varscan2
- EDNRB | c.1282C>G p.P428A (on ENST00000377211 / NM_001201397.1; = p.P338A on NM_000115.5) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100526858; called by muse, mutect2, varscan2
- EDNRB | c.704T>A p.L235Q (on ENST00000377211 / NM_001201397.1; = p.L145Q on NM_000115.5) | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100526860; called by muse, mutect2, varscan2
- EEF2K | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99533417; called by muse, mutect2, varscan2
- EPHB6 | c.991C>G p.P331A | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.028); catalogued as COSV101235988, COSV67417167; called by muse, mutect2, varscan2
- FAM110A | c.657G>T p.L219F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1483719349, COSV99856769; called by muse, mutect2, varscan2
- FAM117A | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99544995; called by muse, mutect2, varscan2
- FAM47C | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100792825, COSV63730563; called by muse, mutect2, varscan2
- FAM47C | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1240526627, COSV100792826; called by muse, mutect2, varscan2
- FAM81A | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV55676542, COSV99893441; called by muse, mutect2, varscan2
- FAP | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99502353; called by muse, mutect2, varscan2
- FCRL2 | c.695C>G p.T232R | Missense Mutation (SNP) | VAF 174/496 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100829963, COSV100830003; called by muse, mutect2, varscan2
- FGA | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 117/373 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV100120566; called by muse, mutect2, varscan2
- FOXK1 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100195534, COSV61066253; called by muse, mutect2, varscan2
- FSTL5 | c.882G>T p.L294F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100058561; called by muse, mutect2
- GAB3 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 68/164 reads (41%) | catalogued as COSV100850656; called by muse, mutect2, varscan2
- GABPB1 | c.416C>G p.T139S | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99589946; called by muse, mutect2, varscan2
- GABRA2 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 153/500 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.077); catalogued as COSV100734587; called by muse, mutect2, varscan2
- GALK2 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100175367, COSV54811371; called by muse, mutect2, varscan2
- GC | c.794G>C p.C265S | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99909973; called by muse, mutect2, varscan2
- GHR | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100051455; called by muse, mutect2, varscan2
- GIMAP6 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 200/625 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100188329; called by muse, mutect2, varscan2
- GKAP1 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100897702; called by muse, mutect2, varscan2
- GNA12 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99282848; called by muse, mutect2, varscan2
- GOLGA5 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.047); catalogued as COSV99371100; called by muse, mutect2, varscan2
- GPR158 | c.1293C>A p.D431E | Missense Mutation (SNP) | VAF 149/468 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV100894016; called by muse, mutect2, varscan2
- GPR35 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.074); catalogued as COSV100166599; called by muse, mutect2, varscan2
- GRID1 | c.352C>G p.R118G | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100025305; called by muse, mutect2, varscan2
- GRIK2 | c.2407G>C p.G803R | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100027725; called by muse, mutect2
- GTDC1 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 48/181 reads (27%) | catalogued as COSV99601232; called by muse, mutect2, varscan2
- H6PD | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101072506; called by muse, mutect2, varscan2
- HAS2 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100392061; called by muse, mutect2, varscan2
- HSPA1A | c.1917G>T p.E639D | Missense Mutation (SNP) | VAF 136/254 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100989422; called by muse, mutect2, varscan2
- HTR2C | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99350203; called by muse, mutect2, varscan2
- ITGA8 | c.891+1G>T p.X297_splice | Splice Site (SNP) | VAF 31/132 reads (23%) | catalogued as COSV100959496; called by muse, mutect2, varscan2
- ITGB3 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV101457646; called by muse, mutect2, varscan2
- ITPR3 | c.4158G>T p.K1386N | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100967732; called by muse, mutect2, varscan2
- KCNN4 | c.859C>G p.R287G | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV99487119; called by muse, mutect2, varscan2
- KEAP1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50261845, COSV50288245; called by muse, mutect2, varscan2
- KIAA0232 | c.1667A>C p.D556A | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100300935; called by muse, mutect2, varscan2
- KIAA0232 | c.3629G>T p.C1210F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100300938; called by muse, mutect2, varscan2
- KIF24 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100799240; called by muse, mutect2, varscan2
- KLHL1 | c.1657G>T p.G553C | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64774775; called by muse, mutect2, varscan2
- KMT2C | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074472, COSV51277484, COSV51455188; called by muse, mutect2
- KRT6B | c.755+2T>C p.X252_splice | Splice Site (SNP) | VAF 93/286 reads (33%) | catalogued as COSV99360872; called by muse, mutect2, varscan2
- LAMA2 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV70348798, COSV70352821; called by muse, mutect2, varscan2
- LAMA4 | c.3019G>T p.E1007* (on ENST00000230538 / NM_001105206.3; = p.E1000* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/218 reads (5%) | catalogued as COSV100038920; called by muse, mutect2
- LAMC2 | c.2997C>A p.S999R | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV99917684; called by muse, mutect2, varscan2
- LCT | c.4664-1G>A p.X1555_splice | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99929984; called by muse, mutect2, varscan2
- LCT | c.3545C>A p.A1182D | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as COSV99070185, COSV99929985; called by muse, mutect2, varscan2
- LDB2 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 239/800 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100454252; called by muse, varscan2
- LHX8 | c.714+1G>T p.X238_splice | Splice Site (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99634077; called by muse, mutect2, varscan2
- LRRC32 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV52636197; called by muse, mutect2, varscan2
- LRRK1 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99441657; called by muse, mutect2, varscan2
- LY6E | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 235/403 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99465122; called by muse, mutect2, varscan2
- LYAR | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.09); catalogued as COSV100603532; called by muse, mutect2, varscan2
- MAGEA11 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100290602; called by muse, mutect2, varscan2
- MAN2A1 | c.539G>T p.W180L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99811546; called by muse, mutect2, varscan2
- MANF | c.542A>C p.D181A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV99813737; called by muse, mutect2, varscan2
- MAOB | c.1542G>C p.R514S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100956161; called by muse, mutect2, varscan2
- MBD5 | c.4197G>A p.W1399* | Nonsense Mutation (SNP) | VAF 62/194 reads (32%) | catalogued as COSV101290181; called by muse, mutect2, varscan2
- MGAT5 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.124); catalogued as COSV99924788; called by muse, mutect2, varscan2
- MICAL2 | c.4898C>T p.P1633L | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV99812061; called by muse, mutect2, varscan2
- MOXD1 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs774838076, COSV100381746; called by muse, mutect2, varscan2
- MUC16 | c.32566A>T p.S10856C | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV101200534; called by muse, mutect2, varscan2
- MUC5B | c.11063G>A p.G3688E | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101500571; called by muse, mutect2, varscan2
- MVP | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1196393603, COSV100651657, COSV62421595; called by muse, mutect2, varscan2
- MYCBPAP | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 124/370 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV60407765; called by muse, mutect2, varscan2
- NFATC1 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99502179; called by muse, mutect2, varscan2
- NIPAL3 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50233703, COSV99135389; called by muse, mutect2, varscan2
- NLRP4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100016749; called by muse, mutect2, varscan2
- NPY4R | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV65399567; called by muse, mutect2
- NPY4R | c.113T>G p.V38G | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100966187; called by muse, mutect2
- NR1H3 | c.1074G>T p.L358F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100211736; called by muse, mutect2, varscan2
- NRXN2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 99/510 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1247344629, COSV99635059; called by muse, mutect2, varscan2
- OPN5 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV99789944; called by muse, mutect2
- OR10G7 | c.825C>A p.Y275* | Nonsense Mutation (SNP) | VAF 81/140 reads (58%) | catalogued as COSV100390002; called by muse, mutect2, varscan2
- OR2T3 | c.897C>A p.N299K | Missense Mutation (SNP) | VAF 96/662 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1486425074, COSV100613310; called by muse, varscan2
- OR4D9 | c.567C>G p.C189W | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100259913; called by muse, mutect2, varscan2
- OR4M1 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 145/868 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60060360, COSV60061531; called by muse, mutect2, varscan2
- OR56A4 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100417634; called by muse, varscan2
- OR8H2 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 20/518 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57943391; called by muse, mutect2
- OR8J3 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100040944; called by muse, mutect2, varscan2
- OR8K3 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.17); catalogued as COSV100449838; called by muse, mutect2, varscan2
- OXSR1 | c.1319T>C p.L440S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1410743876, COSV100309544; called by muse, mutect2, varscan2
- PAPPA | c.2835del p.Y946Tfs*18 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | catalogued as COSV60290828; called by mutect2, pindel, varscan2
- PAX5 | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100814252, COSV63913585; called by muse, mutect2, varscan2
- PAX9 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100825832; called by muse, mutect2, varscan2
- PCDH15 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100224442, COSV57314634; called by muse, mutect2, varscan2
- PCDH8 | c.3088G>T p.V1030F | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100131909, COSV58811149; called by muse, mutect2, varscan2
- PCDHA5 | c.1373A>T p.Q458L | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100972449; called by muse, mutect2, varscan2
- PCNX3 | c.5765C>T p.P1922L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as rs771899959, COSV100856532; called by muse, mutect2, varscan2
- PIGG | c.2261+1G>T p.X754_splice (on ENST00000453061 / NM_001127178.3; = p.X746_splice on NM_017733.4) | Splice Site (SNP) | VAF 18/72 reads (25%) | catalogued as CS164279, COSV99574129; called by muse, mutect2
- PLEKHA6 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1157499639, COSV99692452; called by muse, mutect2, varscan2
- PLEKHG4B | c.3224G>C p.R1075P (on ENST00000283426; = p.R1431P on NM_052909.5) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs185255672, COSV52057041, COSV99360736; called by muse, mutect2, varscan2
- PNLIPRP1 | c.330+2T>C p.X110_splice | Splice Site (SNP) | VAF 50/160 reads (31%) | catalogued as COSV100724471; called by muse, mutect2, varscan2
- PPFIA2 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100334472; called by muse, mutect2
- PRAG1 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100422507, COSV58162190; called by muse, mutect2, varscan2
- PRKCG | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV99669301; called by muse, mutect2, varscan2
- PRPF3 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100254970; called by muse, mutect2, varscan2
- PTPRZ1 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV101100523; called by muse, mutect2, varscan2
- PTPRZ1 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770882408, COSV101100525; called by muse, mutect2, varscan2
- PYHIN1 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 60/233 reads (26%) | PolyPhen benign (0.015); catalogued as COSV100932638, COSV100932685; called by muse, mutect2, varscan2
- QRFPR | c.278T>A p.L93H | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100543859; called by muse, mutect2, varscan2
- RASSF8 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99280910; called by muse, mutect2, varscan2
- RDH16 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100660150, COSV62458068; called by muse, mutect2, varscan2
- REG3A | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs190335034, COSV59412327; called by muse, mutect2, varscan2
- REG3A | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV59408988; called by muse, mutect2, varscan2
- RELCH | c.251del p.G84Afs*25 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as COSV99901827; called by mutect2, pindel, varscan2
- RETREG2 | c.1571G>T p.G524V | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV99811639; called by muse, mutect2, varscan2
- RFX6 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263989, COSV60584122; called by muse, mutect2, varscan2
- RGS12 | c.3568T>C p.F1190L | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV100123138; called by muse, mutect2, varscan2
- RGS7BP | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV61834297; called by muse, mutect2, varscan2
- RNF113B | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 85/247 reads (34%) | catalogued as COSV99940389; called by muse, mutect2, varscan2
- RNF113B | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV99940393; called by muse, mutect2, varscan2
- RPS6KC1 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV65302871; called by muse, mutect2, varscan2
- RTCA | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 188/582 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs145539292, COSV99560029; called by muse, mutect2, varscan2
- RTTN | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99733203; called by muse, mutect2, varscan2
- RUNX1T1 | c.27G>T p.W9C | Missense Mutation (SNP) | VAF 89/632 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV99753495; called by muse, mutect2, varscan2
- RYR1 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616404; called by muse, mutect2, varscan2
- RYR1 | c.1960G>A p.G654S | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100616407; called by muse, mutect2, varscan2
- RYR1 | c.2503G>T p.G835W | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs763120698, COSV100616408; called by muse, mutect2, varscan2
- RYR2 | c.2558C>G p.P853R | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100772013; called by muse, mutect2, varscan2
- RYR2 | c.5999A>T p.H2000L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100772014; called by muse, mutect2, varscan2
- SAXO1 | c.510A>T p.R170S | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.904); catalogued as COSV101000183; called by muse, mutect2, varscan2
- SAXO1 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101000184; called by muse, mutect2, varscan2
- SCG2 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 186/573 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100544823; called by muse, mutect2, varscan2
- SEPTIN3 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV99352264; called by muse, mutect2, varscan2
- SERPINA12 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100369757; called by muse, mutect2, varscan2
- SFSWAP | c.2564G>T p.R855L | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.165); catalogued as rs777681116, COSV99906256; called by muse, mutect2, varscan2
- SGPL1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs750993580, COSV54737218; called by muse, mutect2, varscan2
- SGSM1 | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs1465654198, COSV101240947; called by muse, mutect2, varscan2
- SH3TC2 | c.2361del p.Q788Sfs*21 | Frame Shift Del (DEL) | VAF 48/117 reads (41%) | catalogued as rs1277541041; called by mutect2, pindel, varscan2
- SLC22A5 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as CM100213, COSV99810072; called by muse, mutect2, varscan2
- SLC25A52 | c.149C>T p.A50V (on ENST00000672005; = p.A40V on NM_001034172.4) | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1405287694, COSV99329718; called by muse, mutect2, varscan2
- SLC27A3 | c.1672G>T p.G558C (on ENST00000271857; = p.G430C on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670051; called by muse, mutect2, varscan2
- SLC35G3 | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1434375839, COSV99268950; called by muse, mutect2, varscan2
- SLCO2B1 | c.1678C>A p.L560M | Missense Mutation (SNP) | VAF 134/624 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99214914; called by muse, mutect2, varscan2
- SMC3 | c.1982G>T p.R661L | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV62421429, COSV62423179; called by muse, mutect2, varscan2
- SPTBN1 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61692287, COSV61696208; called by muse, mutect2, varscan2
- SPTBN4 | c.4636G>A p.G1546S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs1400801182, COSV100151580; called by muse, mutect2, varscan2
- SPTBN5 | c.5448G>T p.Q1816H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100311861; called by muse, mutect2
- STAC2 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs1239445624, COSV100336444; called by muse, mutect2, varscan2
- SYT7 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV99801918; called by muse, mutect2, varscan2
- TAS2R50 | c.518A>G p.H173R | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV101115223; called by muse, mutect2, varscan2
- TENM3 | c.7761C>A p.N2587K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV101305286, COSV69306153; called by muse, mutect2, varscan2
- TFEC | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99624914; called by muse, mutect2, varscan2
- TGM2 | c.943T>A p.Y315N | Missense Mutation (SNP) | VAF 102/320 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.516); catalogued as COSV100821695; called by muse, mutect2, varscan2
- TKTL2 | c.1019T>A p.I340N | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99761595; called by muse, mutect2, varscan2
- TLE1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100916001; called by muse, mutect2, varscan2
- TMEM161B | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as COSV99680667; called by muse, mutect2, varscan2
- TMEM63A | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100834421; called by muse, mutect2, varscan2
- TMOD3 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100419158; called by muse, mutect2, varscan2
- TNKS | c.3266G>T p.G1089V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV100127526; called by muse, mutect2, varscan2
- TNN | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV99512510; called by muse, mutect2, varscan2
- TNRC18 | c.5454G>T p.E1818D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV68163616; called by muse, mutect2, varscan2
- TPR | c.4001G>T p.R1334L | Missense Mutation (SNP) | VAF 100/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100824122; called by muse, mutect2, varscan2
- TRIM42 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53885114, COSV53885345; called by muse, mutect2, varscan2
- TRIM9 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100031840; called by muse, mutect2, varscan2
- TRPA1 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 577/848 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100084725, COSV51572922; called by muse, mutect2, varscan2
- TSGA10 | c.983G>T p.R328I | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV100747679; called by muse, mutect2, varscan2
- TTN | c.58856A>G p.N19619S (on ENST00000591111; = p.N12195S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | PolyPhen possibly damaging (0.496); catalogued as COSV100621721; called by muse, mutect2, varscan2
- TTN | c.22077C>A p.S7359R (on ENST00000591111; = p.S6432R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | PolyPhen possibly damaging (0.595); catalogued as COSV100621725; called by muse, mutect2, varscan2
- USP13 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.216); catalogued as COSV99831476; called by muse, mutect2, varscan2
- WEE2 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV101285208; called by muse, mutect2, varscan2
- XIRP1 | c.4679C>A p.S1560Y | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100453802; called by muse, mutect2, varscan2
- XPOT | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV100225668; called by muse, mutect2, varscan2
- ZC3H3 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99368242; called by muse, mutect2, varscan2
- ZFHX4 | c.3826G>T p.V1276L | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV99265403; called by muse, mutect2, varscan2
- ZFP42 | c.374A>T p.K125I | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100479036; called by muse, mutect2, varscan2
- ZNF234 | c.1787A>G p.Y596C | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203381138, COSV101468387; called by muse, mutect2, varscan2
- ZNF451 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100675001; called by muse, mutect2, varscan2
- ZNF479 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100482899; called by muse, mutect2, varscan2
- ZNF521 | c.3407T>A p.L1136Q | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.418); catalogued as COSV100832842; called by muse, mutect2, varscan2
- ZNF532 | c.2252G>T p.R751I | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266904; called by muse, mutect2, varscan2
- ZNF600 | c.472A>G p.R158G | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as COSV100593047; called by muse, mutect2, varscan2
- ZNF764 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99411159; called by muse, mutect2, varscan2
- ADGRV1 | c.1509_1509+7delinsA p.X503_splice | Splice Site (DEL) | VAF 12/26 reads (46%) | called by pindel, varscan2*
- ATF7IP | c.2867del p.G956Efs*30 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | called by mutect2, pindel, varscan2
- CFAP74 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- CFB | c.42del p.F14Lfs*10 | Frame Shift Del (DEL) | VAF 204/413 reads (49%) | called by mutect2, pindel, varscan2
- IGLV2-33 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 203/399 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSLNL | c.76del p.A27Lfs*52 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- OGFOD1 | c.1627_*7del | Nonstop Mutation (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel
- RASAL2 | c.202+1del | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- TAAR6 | c.674G>T p.R225I | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- TPTE | c.1340C>A p.S447* (on ENST00000618007 / NM_199261.4; = p.S429* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2, varscan2
- ACER3 | c.720A>G p.T240= | Silent (SNP) | VAF 93/382 reads (24%) | catalogued as COSV99568603; called by muse, mutect2, varscan2
- AHSG | c.57C>A p.A19= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV99890197; called by muse, varscan2
- ANK2 | c.6081T>G p.V2027= | Silent (SNP) | VAF 60/172 reads (35%) | catalogued as COSV100002968; called by muse, varscan2
- ARHGEF12 | c.4344G>T p.V1448= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as COSV100755072; called by muse, mutect2
- ASMTL | c.687C>T p.I229= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV67243418; called by muse, mutect2
- CACNA1C | c.2391G>T p.G797= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100220511; called by muse, mutect2, varscan2
- CALB2 | c.639C>A p.G213= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100226343; called by muse, mutect2, varscan2
- CEP350 | c.5124C>T p.A1708= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as COSV100854987; called by muse, mutect2, varscan2
- CMPK2 | c.906T>C p.I302= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as rs980722901, COSV99878945; called by muse, mutect2, varscan2
- COL22A1 | c.4338A>T p.P1446= | Silent (SNP) | VAF 56/429 reads (13%) | catalogued as rs1158521855, COSV100279523; called by muse, mutect2, varscan2
- CSRNP3 | c.861G>C p.T287= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV100086086, COSV58776344; called by muse, mutect2, varscan2
- EDEM3 | c.990T>C p.P330= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as rs546692741, COSV100545520; called by muse, mutect2, varscan2
- EDIL3 | c.1437G>A p.E479= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV99678085; called by muse, mutect2, varscan2
- EFCAB5 | c.4470T>C p.Y1490= | Silent (SNP) | VAF 115/286 reads (40%) | catalogued as rs373487186, COSV57927221; called by muse, mutect2, varscan2
- EPHA7 | c.1089G>T p.V363= | Silent (SNP) | VAF 81/157 reads (52%) | catalogued as COSV100994026; called by muse, mutect2, varscan2
- ESF1 | c.15A>G p.Q5= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV99176445; called by muse, mutect2, varscan2
- ESPL1 | c.2169C>T p.L723= | Silent (SNP) | VAF 69/228 reads (30%) | catalogued as COSV99229542; called by muse, mutect2, varscan2
- F13B | c.396G>C p.V132= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV100803356; called by muse, mutect2, varscan2
- GRID1 | c.135A>T p.V45= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100025306; called by muse, mutect2, varscan2
- HAS2 | c.15G>A p.R5= | Silent (SNP) | VAF 89/169 reads (53%) | catalogued as COSV100392059; called by muse, mutect2, varscan2
- HECW1 | c.423C>A p.I141= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV101224056; called by muse, mutect2, varscan2
- ITGA7 | c.1530A>G p.A510= (on ENST00000555728; = p.A466= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as COSV99149733; called by muse, mutect2, varscan2
- LAMA4 | c.3018G>T p.L1006= (on ENST00000230538 / NM_001105206.3; = p.L999= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/216 reads (4%) | catalogued as COSV100038926; called by muse, mutect2
- MAGEC3 | c.1260A>T p.S420= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100025804; called by muse, mutect2, varscan2
- MPO | c.951G>T p.P317= | Silent (SNP) | VAF 74/259 reads (29%) | catalogued as COSV56566483, COSV99832871; called by muse, mutect2, varscan2
- MRGPRD | c.965G>A p.*322= | Silent (SNP) | VAF 108/213 reads (51%) | catalogued as COSV100483054, COSV58422730; called by muse, mutect2, varscan2
- NCAM2 | c.1062C>A p.I354= | Silent (SNP) | VAF 59/201 reads (29%) | catalogued as COSV53056918, COSV53083168, COSV99524164; called by muse, mutect2, varscan2
- NOS2 | c.2082C>A p.I694= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100569785; called by muse, mutect2, varscan2
- NR1I3 | c.939T>C p.Y313= (on ENST00000367982 / NM_001077480.3; = p.Y309= on NM_005122.5) | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs1295404457, COSV100915792; called by muse, mutect2, varscan2
- NRXN1 | c.4350G>A p.G1450= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as COSV100640495; called by muse, mutect2, varscan2
- OR13C5 | c.621A>G p.L207= | Silent (SNP) | VAF 138/468 reads (29%) | catalogued as rs1180083524, COSV101053142; called by muse, mutect2, varscan2
- OR1L6 | c.15C>T p.Y5= | Silent (SNP) | VAF 59/201 reads (29%) | catalogued as COSV100490954; called by muse, mutect2, varscan2
- OR2C1 | c.711G>A p.A237= | Silent (SNP) | VAF 66/205 reads (32%) | catalogued as rs755845257, COSV100514984; called by muse, mutect2, varscan2
- OSBPL3 | c.2247G>A p.R749= | Silent (SNP) | VAF 98/275 reads (36%) | catalogued as rs1305160022, COSV100514355; called by mutect2, varscan2
- PDE10A | c.471G>A p.Q157= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV100605381; called by muse, mutect2
- PGM5 | c.831T>A p.L277= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV101123502; called by muse, mutect2, varscan2
- PLPPR4 | c.889C>A p.R297= | Silent (SNP) | VAF 57/182 reads (31%) | catalogued as COSV64564125, COSV64567002; called by muse, mutect2, varscan2
- PTPN13 | c.7113G>A p.L2371= (on ENST00000411767 / NM_080683.3; = p.L2352= on NM_006264.3) | Silent (SNP) | VAF 75/219 reads (34%) | catalogued as COSV57408099; called by muse, mutect2, varscan2
- PTPRZ1 | c.984T>C p.L328= | Silent (SNP) | VAF 70/221 reads (32%) | catalogued as COSV101100524; called by muse, mutect2, varscan2
- RENBP | c.408C>T p.F136= | Silent (SNP) | VAF 66/131 reads (50%) | catalogued as COSV100129521, COSV60070983; called by muse, mutect2, varscan2
- RIMS4 | c.462C>T p.I154= | Silent (SNP) | VAF 229/747 reads (31%) | catalogued as COSV100865178; called by muse, varscan2
- ROBO3 | c.981G>T p.V327= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV101185120; called by muse, mutect2, varscan2
- RPH3A | c.1320C>A p.A440= (on ENST00000389385 / NM_001143854.2; = p.A436= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as COSV101231859; called by muse, mutect2, varscan2
- SEPTIN14 | c.87G>C p.T29= | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as rs200755602, COSV101193394, COSV66426134; called by muse, mutect2, varscan2
- SFPQ | c.1116C>A p.A372= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV100599480; called by muse, mutect2, varscan2
- SH2D3C | c.438A>T p.V146= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV100137207; called by muse, mutect2, varscan2
- SLC25A14 | c.681G>A p.L227= | Silent (SNP) | VAF 67/144 reads (47%) | catalogued as COSV99502538; called by muse, mutect2, varscan2
- SLITRK5 | c.357C>T p.D119= | Silent (SNP) | VAF 105/353 reads (30%) | catalogued as rs1566319591, COSV100281001; called by muse, mutect2, varscan2
- SPN | c.273G>A p.E91= | Silent (SNP) | VAF 75/300 reads (25%) | catalogued as COSV100788863; called by muse, mutect2, varscan2
- STXBP5 | c.2700A>T p.S900= (on ENST00000321680 / NM_001127715.2; = p.S864= on NM_139244.4) | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV99470649; called by muse, mutect2, varscan2
- TARBP1 | c.1458C>G p.P486= | Silent (SNP) | VAF 61/178 reads (34%) | catalogued as COSV99241883; called by muse, mutect2, varscan2
- TMEM135 | c.210A>G p.Q70= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as rs1210264795, COSV100449933; called by muse, mutect2, varscan2
- TMX4 | c.657A>T p.P219= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV99851569; called by muse, mutect2, varscan2
- TNFSF11 | c.828C>T p.N276= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as rs199774248, CD073711, COSV99520548; called by muse, mutect2, varscan2
- TRIM49 | c.321C>T p.D107= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as COSV100316166; called by muse, mutect2, varscan2
- TTR | c.147C>A p.A49= | Silent (SNP) | VAF 78/173 reads (45%) | catalogued as rs11081703, COSV99379595; called by muse, mutect2, varscan2
- ZFHX4 | c.10503C>G p.T3501= | Silent (SNP) | VAF 167/270 reads (62%) | catalogued as COSV99265406; called by muse, mutect2, varscan2
- ZFYVE1 | c.1119G>T p.G373= | Silent (SNP) | VAF 55/209 reads (26%) | catalogued as rs746544756, COSV100606953; called by muse, mutect2, varscan2
- ZNF473 | c.306A>G p.L102= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV99568995; called by muse, mutect2, varscan2
- CADM3 | c.89-2130C>A | Intron (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100930368; called by muse, mutect2, varscan2
- EPDR1 | c.-77G>T | 5'UTR (SNP) | VAF 26/94 reads (28%) | catalogued as COSV99554570; called by muse, mutect2, varscan2
- FOLH1B | n.1451G>T | RNA (SNP) | VAF 71/331 reads (21%) | called by muse, mutect2, varscan2
- H3-3B | chr17:75784730 G>A | 5'Flank (SNP) | VAF 18/82 reads (22%) | catalogued as COSV53148296; called by muse, mutect2, varscan2
- MIF4GD | c.82+701G>C | Intron (SNP) | VAF 69/249 reads (28%) | catalogued as COSV55453011, COSV99821672; called by muse, mutect2, varscan2
- MIR182 | n.75G>T | RNA (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- NALCN | c.1765-4860G>T | Intron (SNP) | VAF 64/242 reads (26%) | catalogued as COSV99216534; called by muse, mutect2, varscan2
- OR3A4P | n.1109T>C | RNA (SNP) | VAF 102/217 reads (47%) | called by muse, mutect2, varscan2
- SSPOP | n.15354G>C | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100947718; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+658G>T | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99526347; called by muse, mutect2, varscan2
